Somatic mutation profile of tumor specimen 0DY43X from CCDI case PBCSFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.0 years (1,474 days).
Specimen 0DY43X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8172e1ed-6154-4652-b3e7-4e5815d94969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY44K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da2e8710-453f-4cd5-b77e-f15dc31ec58d

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, 3'UTR 1, In Frame Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 46/1176 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs979372722; called by muse, mutect2
- BZW1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 240/1476 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as rs1433314468; called by muse, mutect2, varscan2
- CAPN10 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 52/1028 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.03); catalogued as rs766488505, COSV54379302; called by muse, mutect2
- CERCAM | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 44/1032 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs141407199; called by muse, mutect2
- DBH | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 200/879 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs147521865, COSV67548897; called by muse, mutect2, varscan2
- FAT3 | c.11347G>A p.V3783M | Missense Mutation (SNP) | VAF 215/1028 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs887214312, COSV53085741; called by muse, mutect2, varscan2
- KCNH3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 34/910 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as COSV99235760; called by muse, mutect2
- LRP8 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 91/534 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs1410449156; called by muse, mutect2, varscan2
- NRXN3 | c.1685G>A p.R562H (on ENST00000335750 / NM_001330195.2; = p.R189H on NM_004796.6) | Missense Mutation (SNP) | VAF 137/793 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs369032353; called by muse, mutect2, varscan2
- OBSCN | c.19052C>T p.T6351M | Missense Mutation (SNP) | VAF 73/604 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200636677; called by muse, mutect2, varscan2
- SEH1L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 123/686 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs897578017; called by muse, mutect2, varscan2
- SMPDL3A | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 149/928 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as rs774338598; called by muse, mutect2, varscan2
- SMURF1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 94/1476 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs759637040; called by muse, mutect2
- SSTR1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 28/609 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57455062; called by muse, mutect2
- ST6GALNAC1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 134/1157 reads (12%) | PolyPhen benign (0.006); catalogued as rs777239689; called by muse, mutect2, varscan2
- STARD3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 46/1226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775180395, COSV60420907; called by muse, mutect2
- CABIN1 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 42/1462 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.193); called by muse, mutect2
- CLEC14A | c.1206del p.F402Lfs*2 | Frame Shift Del (DEL) | VAF 150/932 reads (16%) | called by mutect2, pindel, varscan2
- JADE2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 44/505 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2
- LRRK1 | c.4024C>T p.L1342F | Missense Mutation (SNP) | VAF 124/835 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM26 | c.2666G>A p.R889H (on ENST00000438737 / NM_001366735.2; = p.R862H on NM_022118.5) | Missense Mutation (SNP) | VAF 64/1382 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- RNF207 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 81/593 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SERPINA4 | c.1163T>G p.F388C | Missense Mutation (SNP) | VAF 35/885 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.092); called by muse, mutect2
- SRRT | c.1645_1647dup p.T549dup | In Frame Ins (INS) | VAF 109/875 reads (12%) | called by mutect2, pindel, varscan2
- TMEM26 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 178/999 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TNFSF4 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 121/1579 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2
- BECN2 | c.54C>T p.S18= | Silent (SNP) | VAF 100/916 reads (11%) | catalogued as rs927944662; called by muse, mutect2, varscan2
- MIGA2 | c.27G>A p.T9= | Silent (SNP) | VAF 120/710 reads (17%) | catalogued as rs778117776; called by muse, mutect2, varscan2
- PDK2 | c.399C>T p.G133= | Silent (SNP) | VAF 246/962 reads (26%) | catalogued as rs761025550, COSV50304108; called by muse, mutect2, varscan2
- SLC25A41 | c.873A>G p.L291= | Silent (SNP) | VAF 326/629 reads (52%) | called by muse, mutect2, varscan2
- TELO2 | c.2088C>T p.A696= | Silent (SNP) | VAF 73/615 reads (12%) | catalogued as rs766119507; called by muse, mutect2, varscan2
- ATXN7L1 | c.355+27248C>T | Intron (SNP) | VAF 40/802 reads (5%) | catalogued as rs776035500, COSV59494191; called by muse, mutect2
- MARCHF3 | c.*33T>C | 3'UTR (SNP) | VAF 41/958 reads (4%) | called by muse, mutect2
